Gene-level copy-number profile of tumor specimen ALCH-B4F1-TTP1-A from ALCHEMIST case ALCH-B4F1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.7 years (28,389 days).
Specimen ALCH-B4F1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f483f536-2521-40b6-9666-ef11b12ef796.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4F1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/7d2c6b21-cbd6-4d48-b162-85d370a37a83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 4,195; copy number 2: 52,457; copy number 3: 2,162; copy number 4: 21; copy number 5: 8; copy number 6: 7; copy number 21: 1; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:73,055,097–73,055,857, 1 gene (within-gene range 0–2): PGAM1P10.
- chr6:159,383,422–159,401,147, 1 gene: LINC02529.
- chr7:75,156,639–75,395,383, 17 genes (within-gene range 0–20): NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA.
- chr7:98,322,853–98,323,430, 1 gene (within-gene range 0–2): AC093799.1.
- chr9:104,270,228–104,286,955, 1 gene: TOPORSLP.
- chr10:79,870,375–79,873,903, 1 gene: CTSLP6.
- chr11:1,469,457–1,501,247, 1 gene: MOB2.
- chr11:69,083,176–69,083,258, 1 gene (within-gene range 0–2): MIR3164.
- chr11:112,074,086–112,086,798, 2 genes (within-gene range 0–2): NKAPD1, TIMM8B.
- chr16:28,364,700–28,415,018, 4 genes: AC138894.3, EIF3CL, MIR6862-1, CDC37P2.
- chr16:88,651,935–88,663,161, 1 gene: MVD.
- chr17:3,662,895–3,668,679, 1 gene (within-gene range 0–2): TAX1BP3.
- chr17:3,665,220–3,665,702, 1 gene (within-gene range 0–2): AC132942.1.
- chr19:11,296,139–11,326,996, 2 genes (within-gene range 0–2): TSPAN16, AC011472.2.
- chr19:11,322,156–11,324,195, 1 gene (within-gene range 0–2): AC011472.3.
- chr20:23,481,645–23,519,054, 3 genes (within-gene range 0–2): AL109954.1, AL109954.2, CST8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,632,608–63,636,617, 1 gene, copy number 22: AC006015.1.
- chr7:73,736,094–73,770,270, 2 genes, copy number 5: ABHD11, CLDN3.
- chr11:797,511–812,880, 4 genes, copy number 6 (within-gene range 2–6): AP006621.6, PIDD1, RPLP2, SNORA52.
- chr14:104,800,596–104,804,712, 1 gene, copy number 5: ZBTB42.
- chr17:82,031,678–82,037,709, 3 genes, copy number 5: RAC3, DCXR, AC137723.1.
- chr22:21,341,595–21,345,258, 1 gene, copy number 21: PPP1R26P5.

Autosomal genes at a single copy (total copy number 1): 1,408. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
